Somatic mutation profile of tumor specimen TCGA-61-1914-01A (aliquot TCGA-61-1914-01A-01W-0639-09) from TCGA case TCGA-61-1914, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.3 years (23,850 days).
Specimen TCGA-61-1914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10e48d1-d47b-411a-b8ab-728504cb743e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1914-11A (Solid Tissue Normal), aliquot TCGA-61-1914-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5ffe024-0770-463e-8b5e-96da45163552

The open-access MAF lists 111 somatic variants for this specimen: 86 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 24, Nonsense Mutation 8, Frame Shift Del 7, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1421T>G p.L474* | Nonsense Mutation (SNP) | VAF 162/222 reads (73%) | catalogued as rs80357490, CM021505, COSV58783349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>C p.C275S | Missense Mutation (SNP) | VAF 58/95 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADGRF2 | c.1364G>A p.G455D (on ENST00000296862 / NM_001368115.2; = p.G387D on NM_153839.7) | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57286179; called by muse, mutect2, varscan2
- AMPD3 | c.1274C>A p.A425D (on ENST00000396553 / NM_001025389.2; = p.A434D on NM_000480.3) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.815); catalogued as COSV101158300; called by muse, mutect2
- ANK2 | c.3130C>T p.L1044F | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs1185161404, COSV52143588; called by muse, mutect2, varscan2
- ANO6 | c.2247G>T p.M749I | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV57656012; called by muse, mutect2, varscan2
- ATP11C | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.496); catalogued as COSV59558862; called by muse, mutect2, varscan2
- C1orf87 | c.1173G>T p.L391F | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV64595909; called by muse, mutect2, varscan2
- CAPN6 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 123/956 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as COSV60693652; called by muse, mutect2, varscan2
- CARM1 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV58998633; called by muse, mutect2, varscan2
- CARM1 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV53402581; called by muse, mutect2, varscan2
- CARMIL3 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.36); catalogued as rs774706113, COSV100549297; called by muse, mutect2
- CD163L1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV100550159, COSV58010301; called by muse, mutect2, varscan2
- CD200R1L | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV101236566; called by muse, mutect2
- CDH11 | c.1580T>G p.F527C | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV51750134; called by muse, mutect2, varscan2
- CDH16 | c.1686dup p.K563Qfs*41 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | catalogued as rs776664434; called by pindel, varscan2
- CDK17 | c.900_912del p.L301Ifs*10 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as COSV54126220; called by mutect2, pindel, varscan2
- CEP70 | c.998A>C p.E333A | Missense Mutation (SNP) | VAF 113/321 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.35); catalogued as COSV53873827; called by muse, mutect2, varscan2
- CNGA2 | c.1874C>A p.A625D | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV61702910; called by muse, mutect2, varscan2
- CNGB3 | c.1554C>G p.I518M | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100182156; called by muse, mutect2
- COL6A6 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.948); catalogued as rs753052794, COSV62016580; called by muse, mutect2, varscan2
- DISP3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs1303874871, COSV53819302; called by muse, mutect2, varscan2
- DNAH6 | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV52847854; called by muse, mutect2, varscan2
- EHD1 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as COSV100276941; called by muse, varscan2
- ERI1 | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV51570440; called by muse, mutect2, varscan2
- EXD1 | c.224A>T p.E75V | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100153563; called by muse, mutect2
- EXOC3 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as COSV100155248; called by muse, mutect2
- F5 | c.2527G>T p.D843Y | Missense Mutation (SNP) | VAF 189/509 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV63120022; called by muse, mutect2, varscan2
- FLG2 | c.4492G>A p.G1498R | Missense Mutation (SNP) | VAF 30/840 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1177389890, COSV101165748; called by muse, mutect2
- GPR148 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as COSV59307420; called by muse, mutect2, varscan2
- GTF3C1 | c.4274_4289del p.H1425Rfs*3 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as COSV62238516; called by mutect2, varscan2
- HERC1 | c.1848T>G p.I616M | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV71245751; called by muse, mutect2, varscan2
- HNF4A | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV57378748; called by muse, mutect2, varscan2
- HTR4 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.56); catalogued as rs1359032855, COSV58795076; called by muse, mutect2
- HYDIN | c.9391G>A p.E3131K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV59248065; called by muse, mutect2, varscan2
- IPO9 | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV64232656; called by muse, mutect2, varscan2
- KCNK10 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.261); catalogued as COSV56638668; called by muse, mutect2, varscan2
- KCTD19 | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 39/185 reads (21%) | catalogued as COSV58570862; called by muse, mutect2, varscan2
- L1TD1 | c.2137T>G p.Y713D | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV63133008; called by muse, mutect2
- L1TD1 | c.2546A>G p.Y849C | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63133017; called by muse, mutect2, varscan2
- LENG8 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1220062409, COSV58730538; called by muse, mutect2
- LIG3 | c.2387C>A p.T796K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs947282793, COSV52005414; called by muse, mutect2, varscan2
- LRIG1 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56236134; called by muse, mutect2, varscan2
- MBOAT1 | c.322A>T p.R108* | Nonsense Mutation (SNP) | VAF 119/186 reads (64%) | catalogued as COSV61123265; called by muse, mutect2, varscan2
- MC3R | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 104/391 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1286756644, COSV54762849; called by mutect2, varscan2
- MRO | c.391A>C p.I131L | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV56494689; called by muse, mutect2, varscan2
- MSRB3 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 19/197 reads (10%) | catalogued as COSV57592355; called by muse, mutect2, varscan2
- NAA11 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs529712269, COSV54513746; called by muse, mutect2, varscan2
- NMNAT2 | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV54266055, COSV99679747; called by muse, mutect2, varscan2
- NOD2 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.114); catalogued as COSV56047957; called by muse, mutect2, varscan2
- NPAS2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV59554753; called by muse, mutect2, varscan2
- NR4A1 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as COSV54479731, COSV99671159; called by muse, mutect2
- OGA | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.283); catalogued as rs1242330518, COSV63380758; called by muse, mutect2, varscan2
- OR2A5 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 22/646 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV101278708; called by muse, mutect2
- OR8B12 | c.678C>A p.H226Q | Missense Mutation (SNP) | VAF 113/158 reads (72%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.082); catalogued as COSV60910776; called by mutect2, varscan2
- PAQR3 | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99784980; called by muse, mutect2
- PARP9 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV64449782; called by muse, mutect2, varscan2
- PCDHGA6 | c.1919A>G p.Q640R | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV53891846; called by muse, mutect2, varscan2
- PICALM | c.1848A>T p.Q616H | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV62668877; called by muse, mutect2, varscan2
- PLCH1 | c.1076A>G p.H359R (on ENST00000340059 / NM_001130960.2; = p.H371R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58184733; called by muse, mutect2, varscan2
- PPP4R1 | c.2340C>A p.D780E (on ENST00000400556 / NM_001042388.3; = p.D763E on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV99553346; called by muse, mutect2
- PPP6R3 | c.2078C>G p.T693R (on ENST00000393800 / NM_001352375.2; = p.T613R on NM_018312.5) | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV55720303; called by muse, mutect2, varscan2
- PRRC2A | c.676C>G p.H226D | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs779936841, COSV63224243; called by muse, mutect2, varscan2
- RAMP3 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54244670; called by muse, mutect2, varscan2
- REC8 | c.1491C>G p.D497E | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100268938; called by muse, mutect2
- RIPK1 | c.1712A>G p.K571R | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV99454246; called by muse, mutect2
- RLF | c.1844C>A p.S615Y | Missense Mutation (SNP) | VAF 6/158 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV101035206; called by muse, mutect2
- RSPH14 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53266525; called by muse, mutect2
- SENP7 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.991); catalogued as rs749197532, COSV58607151; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 106/252 reads (42%) | PolyPhen benign (0.01); catalogued as rs775223600, COSV50073438; called by muse, mutect2, varscan2
- SUOX | c.920A>G p.H307R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV99906993; called by muse, mutect2
- TANGO6 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55759665; called by muse, mutect2, varscan2
- TBC1D8 | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV65209421; called by muse, mutect2, varscan2
- TNR | c.4062G>C p.Q1354H | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54867607; called by muse, mutect2, varscan2
- TRIO | c.3198G>C p.Q1066H | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60076700; called by muse, mutect2, varscan2
- UBXN6 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV56677972; called by muse, mutect2, varscan2
- USP34 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | catalogued as COSV68397383; called by muse, mutect2, varscan2
- WSCD2 | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.506); catalogued as COSV99774351; called by muse, mutect2
- ZDHHC17 | c.1814T>C p.L605P | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58349974; called by muse, mutect2, varscan2
- ZNF30 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1397697731, COSV100340445; called by muse, mutect2
- ZNF492 | c.722C>G p.T241S | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs1404232888, COSV101513969; called by muse, mutect2, varscan2
- CLEC12B | c.666_680+2del | Frame Shift Del (DEL) | VAF 88/456 reads (19%) | called by mutect2, varscan2
- ITSN1 | c.3757_3775del p.V1253Sfs*9 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel
- OR1A2 | c.698_707del p.L233Pfs*27 | Frame Shift Del (DEL) | VAF 25/256 reads (10%) | called by mutect2, pindel
- SLC51A | c.316_338del p.L106Afs*95 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by pindel, varscan2
- USP45 | c.1449_1494del p.N483Kfs*67 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | called by mutect2, pindel
- ATIC | c.1035A>G p.G345= | Silent (SNP) | VAF 71/219 reads (32%) | catalogued as COSV52691522; called by muse, mutect2, varscan2
- CACNB3 | c.687C>G p.L229= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV99974796; called by muse, mutect2
- CATSPERE | c.2028T>G p.L676= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV63675510; called by muse, mutect2, varscan2
- CD5 | c.876C>A p.R292= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV61717673; called by muse, mutect2, varscan2
- CPNE8 | c.1080T>C p.F360= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as rs750153784, COSV100504151; called by muse, mutect2
- DNAH5 | c.357C>T p.N119= | Silent (SNP) | VAF 155/422 reads (37%) | catalogued as rs1026473277, COSV54201175; called by muse, varscan2
- EHD1 | c.1320G>T p.V440= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs968691483, COSV100276944; called by muse, varscan2
- ELAVL2 | c.900A>T p.G300= | Silent (SNP) | VAF 85/149 reads (57%) | catalogued as COSV56356467; called by muse, mutect2, varscan2
- GLG1 | c.2349C>T p.T783= | Silent (SNP) | VAF 58/91 reads (64%) | catalogued as rs756644056, COSV52663477; called by muse, mutect2, varscan2
- H1-2 | c.120G>A p.V40= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as rs766702432, COSV59189469; called by muse, mutect2
- IRF2BP2 | c.1242G>A p.P414= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV64014486; called by muse, mutect2, varscan2
- LHFPL2 | c.249G>A p.G83= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100982487; called by muse, mutect2
- LRRC6 | c.1335C>G p.P445= | Silent (SNP) | VAF 13/448 reads (3%) | called by muse, mutect2
- LZTR1 | c.717G>A p.K239= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99301534; called by muse, mutect2
- MPP2 | c.558G>A p.L186= (on ENST00000461854 / NM_001278372.2; = p.L162= on NM_005374.5) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV52232707; called by muse, mutect2, varscan2
- NLRP5 | c.3183C>T p.I1061= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV66761658, COSV66761991; called by muse, mutect2, varscan2
- NRAP | c.3513A>G p.S1171= (on ENST00000359988 / NM_001322945.2; = p.S1136= on NM_006175.4) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100748363; called by muse, mutect2
- NUDT16 | c.495C>T p.G165= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1329722139, COSV63248096; called by muse, mutect2, varscan2
- PAH | c.522C>T p.I174= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV61013672; called by muse, mutect2, varscan2
- PCDHB13 | c.2283C>G p.T761= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as COSV99507042; called by muse, mutect2
- RGR | c.414C>T p.F138= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as rs745567392, COSV63893242; called by muse, mutect2, varscan2
- SCARF1 | c.1605T>C p.V535= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99556959; called by muse, mutect2
- THBS2 | c.2589C>T p.D863= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as COSV64676829; called by muse, mutect2
- VPS13C | c.3099C>T p.V1033= (on ENST00000644861 / NM_020821.3; = p.V990= on NM_017684.5) | Silent (SNP) | VAF 56/138 reads (41%) | catalogued as rs573291312, COSV51119896; called by muse, mutect2, varscan2
- CPLANE1 | c.*3707C>A | 3'UTR (SNP) | VAF 25/93 reads (27%) | catalogued as COSV57050626; called by muse, mutect2, varscan2
